Somatic mutation profile of tumor specimen TCGA-A2-A0T6-01A (aliquot TCGA-A2-A0T6-01A-11D-A099-09) from TCGA case TCGA-A2-A0T6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 50.2 years (18,334 days).
Specimen TCGA-A2-A0T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ae6baa0-0cee-4935-965e-3d4b5adac976.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0T6-10A (Blood Derived Normal), aliquot TCGA-A2-A0T6-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/354db8c9-bfbe-4bb4-8a78-d9c4d1160450

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 1, In Frame Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ERBB2 | c.2263T>A p.L755M | Missense Mutation (SNP) | VAF 42/151 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519890, COSV54062219, COSV54066696; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2264T>G p.L755W | Missense Mutation (SNP) | VAF 43/152 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.1821-3dup | Splice Region (INS) | VAF 48/225 reads (21%) | catalogued as rs748641243; called by mutect2, varscan2
- ASAP2 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1197348274, CM138055, COSV55627787; called by muse, mutect2, varscan2
- CMTR1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs1460404631, COSV65089565; called by muse, mutect2, varscan2
- GEMIN5 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.33); catalogued as COSV53558472, COSV53566066; called by muse, mutect2, varscan2
- HS6ST2 | c.1127A>G p.K376R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as COSV63710962; called by muse, mutect2, varscan2
- KCNK2 | c.817G>A p.V273I (on ENST00000444842 / NM_001017425.3; = p.V258I on NM_014217.4) | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs367815630; called by muse, mutect2, varscan2
- MED23 | c.3667C>T p.Q1223* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as rs1275205100, COSV63430433, COSV63433286; called by muse, mutect2, varscan2
- RAI14 | c.1825A>T p.M609L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54289974; called by muse, mutect2, varscan2
- SMAD3 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs779602560, COSV59280881; called by muse, mutect2, varscan2
- TBCC | c.484G>T p.V162F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs769836035, COSV99774017; called by muse, mutect2
- CDH1 | c.2482_2485dup p.S829* | Frame Shift Ins (INS) | VAF 21/64 reads (33%) | called by mutect2, pindel, varscan2
- PTPA | c.399_405delinsG p.R134_F135del (on ENST00000337738 / NM_178001.2; = p.R99_F100del on NM_021131.5) | In Frame Del (DEL) | VAF 13/60 reads (22%) | called by pindel, varscan2*
- FAM107B | c.126G>A p.Q42= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV51679963; called by muse, mutect2, varscan2
- GRK5 | c.921C>T p.T307= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs368066639, COSV100963183; called by mutect2, varscan2
- MELTF | c.1434C>T p.A478= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs113102133, COSV99586569; called by muse, mutect2, varscan2
- NTNG1 | c.234G>A p.T78= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs769781518, COSV53963635; called by muse, mutect2, varscan2
- RP1 | c.702C>T p.I234= | Silent (SNP) | VAF 50/198 reads (25%) | catalogued as COSV55110856, COSV55111916; called by muse, mutect2, varscan2
- XIRP2 | c.6297C>T p.I2099= (on ENST00000628543; = p.I2274= on NM_152381.6) | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs779401246, COSV54684597, COSV54729716; called by muse, mutect2, varscan2
